Somatic mutation profile of tumor specimen MBCProject_4424_T3_WES (aliquot MBCProject_4424_T3_WES_1) from CMI case MBCProject_4424, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_4424_T3_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 984f3da5-39e7-44e5-876e-f0fa74f1e6ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4424_SALIVA (Saliva), aliquot MBCProject_4424_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66f9da1e-878a-4cee-a979-3de46a67ac20

The open-access MAF lists 86 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 16, Intron 5, Nonsense Mutation 4, RNA 3, Splice Site 3, Frame Shift Del 2, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 61/215 reads (28%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ARAP1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1464637374, COSV61990866; called by muse, mutect2
- ATP1A3 | c.1829G>A p.R610H (on ENST00000545399 / NM_001256214.2; = p.R597H on NM_152296.5) | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100132236; called by muse, mutect2, varscan2
- CELSR1 | c.4216C>T p.R1406C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs45551035; called by muse, mutect2, varscan2
- CLCA4 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201747732; called by muse, mutect2
- CLEC3A | c.352G>A p.D118N (on ENST00000651443; = p.D109N on NM_005752.6) | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.681); catalogued as COSV55222580; called by muse, mutect2, varscan2
- DOCK1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs748248819; called by muse, mutect2
- KCNC1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV99789600; called by muse, mutect2, varscan2
- KIF21B | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59766970; called by muse, mutect2, varscan2
- LRRC41 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1214114331; called by muse, mutect2, varscan2
- MME | c.2090C>A p.T697N | Missense Mutation (SNP) | VAF 64/704 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs1280378056; called by muse, mutect2
- PHOX2B | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1476963248, COSV56928452; called by muse, mutect2, varscan2
- PIK3CA | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.609); catalogued as COSV55914371; called by muse, varscan2
- PIK3CD | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as rs1043386158; called by muse, mutect2, varscan2
- RC3H2 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV61801802; called by muse, mutect2, varscan2
- SCN3A | c.2551C>T p.R851* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | catalogued as rs1363400927, COSV51806492; called by muse, mutect2, varscan2
- TREM1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as rs565216476, COSV55149105; called by muse, mutect2, varscan2
- TYR | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs61754372, COSV54485016; ClinVar: not provided; called by muse, mutect2
- USP17L1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 105/325 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.08); catalogued as rs748197376; called by muse, mutect2, varscan2
- ARRDC2 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- CAMSAP2 | c.3148G>C p.V1050L (on ENST00000236925 / NM_001297707.2; = p.V1039L on NM_203459.3) | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHEK1 | c.-20-5T>G | Splice Region (SNP) | VAF 30/187 reads (16%) | called by muse, mutect2, varscan2
- CSMD3 | c.6841+2T>G p.X2281_splice (on ENST00000297405 / NM_001363185.1; = p.X2177_splice on NM_052900.3) | Splice Site (SNP) | VAF 45/682 reads (7%) | called by muse, mutect2
- DNAH10 | c.2432G>C p.W811S (on ENST00000409039; = p.W750S on NM_207437.3) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF2B5 | c.469T>C p.S157P | Missense Mutation (SNP) | VAF 57/536 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPPK1 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- FBXO4 | c.819_820del p.Y273* | Frame Shift Del (DEL) | VAF 71/577 reads (12%) | called by mutect2, pindel, varscan2
- GCC2 | c.3488C>G p.A1163G | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GLYAT | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- GPC4 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRK7 | c.358G>C p.G120R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, varscan2
- GRK7 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.139); called by muse, varscan2
- MAP2 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MFAP3 | c.479C>A p.T160K | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- NCOR1 | c.3565A>T p.R1189* | Nonsense Mutation (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- P4HA3 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PDE11A | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDLIM5 | c.17T>A p.V6E | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PHACTR2 | c.27C>G p.D9E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.14); called by muse, mutect2
- PZP | c.3830G>A p.R1277K | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- RIN1 | c.787C>G p.P263A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- RNF2 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- RPL12 | c.278dup p.K94Efs*6 | Frame Shift Ins (INS) | VAF 14/142 reads (10%) | called by mutect2, pindel
- SETD4 | c.828T>G p.D276E | Missense Mutation (SNP) | VAF 47/563 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- SLC25A3 | c.565C>T p.R189* (on ENST00000228318 / NM_005888.3; = p.R188* on NM_002635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/180 reads (14%) | called by muse, mutect2, varscan2
- SLC25A32 | c.851C>G p.P284R | Missense Mutation (SNP) | VAF 218/545 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SMCHD1 | c.1760A>T p.D587V | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SPTBN2 | c.3884A>T p.D1295V | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- SYNM | c.999_1006+13del p.X333_splice | Splice Site (DEL) | VAF 11/100 reads (11%) | called by mutect2, pindel
- TCEA3 | c.499A>T p.T167S | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD1 | c.3176-4_3181delinsTTTTTTTTTT p.X1059_splice | Splice Site (ONP) | VAF 6/65 reads (9%) | called by mutect2*, pindel
- TDRD15 | c.5583G>T p.W1861C | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- UGDH | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, varscan2
- VPS35L | c.1504T>C p.Y502H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XRCC1 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF579 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF624 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF638 | c.3616A>T p.N1206Y | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZSCAN5B | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ZXDB | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 51/410 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AL031777.2 | c.177G>A p.L59= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as rs1189059173, COSV100587269, COSV61912056; called by muse, mutect2, varscan2
- APBB1 | c.246G>A p.T82= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as rs1186971924, COSV100193685, COSV54976748; called by muse, mutect2, varscan2
- ARHGAP22 | c.1725G>A p.A575= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as rs781427375; called by muse, mutect2, varscan2
- CEP78 | c.1326A>T p.S442= (on ENST00000424347 / NM_001349840.2; = p.S443= on NM_032171.3) | Silent (SNP) | VAF 39/269 reads (14%) | called by muse, mutect2, varscan2
- COL4A2 | c.309C>T p.G103= | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as rs201777404, COSV64626875; called by muse, mutect2, varscan2
- EPHA3 | c.60G>A p.G20= | Silent (SNP) | VAF 26/205 reads (13%) | called by muse, mutect2, varscan2
- FBXO39 | c.792C>T p.H264= | Silent (SNP) | VAF 37/222 reads (17%) | catalogued as rs375399858; called by muse, mutect2, varscan2
- GAS2L2 | c.2430C>T p.P810= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- GRK7 | c.360G>T p.G120= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV53823060; called by muse, varscan2
- HRNR | c.690C>A p.G230= | Silent (SNP) | VAF 46/390 reads (12%) | catalogued as rs748425764, COSV64263095; called by muse, mutect2, varscan2
- IZUMO2 | c.633A>C p.T211= | Silent (SNP) | VAF 29/205 reads (14%) | called by muse, mutect2, varscan2
- KCNB2 | c.408C>T p.C136= | Silent (SNP) | VAF 79/370 reads (21%) | called by muse, mutect2, varscan2
- MGAT2 | c.54C>A p.A18= | Silent (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- PM20D1 | c.63C>T p.T21= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs768855458, COSV65649170; called by muse, mutect2
- PSD2 | c.915C>T p.N305= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as rs769100874; called by muse, mutect2, varscan2
- YY1AP1 | c.642C>T p.I214= (on ENST00000295566 / NM_139118.2; = p.I137= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/232 reads (12%) | catalogued as rs771039438; called by muse, mutect2, varscan2
- AP002008.2 | n.1673C>T | RNA (SNP) | VAF 11/95 reads (12%) | catalogued as rs184988787; called by muse, mutect2, varscan2
- CHRNA1 | c.*32G>A | 3'UTR (SNP) | VAF 30/307 reads (10%) | called by muse, mutect2, varscan2
- FER1L4 | n.3502G>A | RNA (SNP) | VAF 12/112 reads (11%) | catalogued as rs1410476837; called by muse, mutect2
- H2BC18 | c.378-9634G>T | Intron (SNP) | VAF 15/122 reads (12%) | catalogued as rs1203068055; called by muse, mutect2, varscan2
- HSP90AA4P | n.1530C>A | RNA (SNP) | VAF 29/193 reads (15%) | called by muse, mutect2, varscan2
- MASP1 | c.-97G>C | 5'UTR (SNP) | VAF 119/985 reads (12%) | called by muse, mutect2, varscan2
- NRP2 | c.251+30C>A | Intron (SNP) | VAF 37/292 reads (13%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.9327+418G>A | Intron (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- PLD1 | c.2429+4993A>G | Intron (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- WNT8A | c.68+43C>T | Intron (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
